Somatic mutation profile of tumor specimen TCGA-DD-AACM-01A (aliquot TCGA-DD-AACM-01A-11D-A40R-10) from TCGA case TCGA-DD-AACM, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 48.2 years (17,590 days).
Specimen TCGA-DD-AACM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c79a140-84f8-4775-a237-440962d8d3da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACM-10A (Blood Derived Normal), aliquot TCGA-DD-AACM-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21672f69-414d-49ba-840e-2fbe6b9a61ed

The open-access MAF lists 59 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 1, Intron 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 49/164 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARMC5 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1338163719, COSV99192772; called by muse, mutect2
- ATG12 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as COSV99174641; called by muse, mutect2, varscan2
- BPTF | c.3295A>G p.K1099E | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs1169551725, COSV100075852; called by muse, mutect2, varscan2
- CA10 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as rs375126312; called by muse, mutect2, varscan2
- CADM1 | c.1328A>T p.*443Lext*15 | Nonstop Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as COSV100523297; called by muse, mutect2, varscan2
- CD247 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as COSV100758463; called by muse, mutect2, varscan2
- COL19A1 | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100507271, COSV59569173; called by muse, mutect2
- CPNE4 | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101456799; called by muse, mutect2
- CSGALNACT1 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as rs35454485; called by muse, mutect2, varscan2
- DHRS7B | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100684064; called by muse, mutect2, varscan2
- DHX37 | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV100439452, COSV58133254; called by muse, mutect2, varscan2
- DSCAML1 | c.2357C>T p.A786V (on ENST00000321322; = p.A726V on NM_020693.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs147991561, COSV58402136; called by muse, mutect2, varscan2
- FAM71C | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | catalogued as COSV100175809; called by muse, mutect2, varscan2
- FBXW10 | c.1096C>A p.H366N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100111699; called by muse, mutect2, varscan2
- FSCB | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.018); catalogued as COSV100469771; called by muse, mutect2, varscan2
- GABBR1 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100589999; called by muse, mutect2
- GBA2 | c.1045C>G p.H349D | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); catalogued as COSV100803480; called by muse, mutect2, varscan2
- HAND1 | c.364C>G p.P122A | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163980, COSV99164010; called by muse, mutect2, varscan2
- HERC2 | c.7519G>A p.D2507N | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as rs776657606, COSV99876343; called by muse, varscan2
- HERC2 | c.2656G>T p.A886S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs759873703, COSV55314964, COSV99876345; called by muse, mutect2, varscan2
- ITGB7 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs748193418, COSV57239719; called by muse, mutect2, varscan2
- KIAA1109 | c.14227C>T p.R4743C | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767116983, COSV52662892; called by muse, mutect2, varscan2
- MAOB | c.1234A>T p.R412W | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100956212; called by muse, mutect2, varscan2
- MICALL2 | c.2381A>T p.Q794L | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99876227; called by muse, mutect2, varscan2
- MKI67 | c.8257G>C p.D2753H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.069); catalogued as COSV100896922; called by muse, mutect2, varscan2
- PADI3 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs1275283999, COSV100968575; called by muse, mutect2, varscan2
- PPP5C | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV99183642; called by muse, mutect2, varscan2
- SEC24C | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100227119; called by muse, mutect2, varscan2
- SF3B4 | c.1001C>G p.P334R | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as COSV99641278, COSV99641373; called by muse, mutect2, varscan2
- SLC5A4 | c.1450G>T p.G484* | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as COSV99832109; called by muse, mutect2, varscan2
- SLIT3 | c.1885A>T p.S629C | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV100269447; called by muse, mutect2
- SNX30 | c.302A>T p.H101L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100953954; called by muse, mutect2, varscan2
- TAGAP | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100487622; called by muse, mutect2, varscan2
- TMEM43 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV100044533; called by muse, mutect2, varscan2
- TRDN | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 129/433 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100523218; called by muse, mutect2, varscan2
- TRIP6 | c.359G>C p.R120P | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.554); catalogued as COSV99308130; called by muse, mutect2, varscan2
- USP54 | c.3309A>C p.K1103N | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV100357589; called by muse, mutect2, varscan2
- YIPF7 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100274639; called by muse, mutect2
- ZFP28 | c.1094A>T p.N365I | Missense Mutation (SNP) | VAF 86/170 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.271); catalogued as COSV100019820; called by muse, mutect2, varscan2
- KIAA0319L | c.2214G>C p.G738= | Splice Region (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2
- LBHD1 | c.10_14delinsA p.V4Kfs*90 (on ENST00000431002 / NM_001367940.1; = p.V4Kfs*64 on NM_024099.3) | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by pindel, varscan2*
- MLH3 | c.4096_4114del p.I1366* (on ENST00000355774 / NM_001040108.2; = p.I1342* on NM_014381.3) | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- MRC1 | c.1724C>T p.T575I | Missense Mutation (SNP) | VAF 165/828 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NF1 | c.5768_5779del p.T1923_L1927delinsM (on ENST00000358273 / NM_001042492.3; = p.T1902_L1906delinsM on NM_000267.3) | In Frame Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- SLIT2 | c.2542_2543del p.L848Ffs*16 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- APOBEC3B | c.930C>G p.A310= | Silent (SNP) | VAF 35/177 reads (20%) | catalogued as COSV100213860; called by muse, mutect2, varscan2
- ECT2L | c.555C>T p.C185= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV100872165; called by muse, mutect2, varscan2
- ELMOD2 | c.670T>C p.L224= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100063045; called by muse, mutect2, varscan2
- ITIH4 | c.2731A>C p.R911= | Silent (SNP) | VAF 55/163 reads (34%) | catalogued as COSV99819796; called by muse, mutect2, varscan2
- LRP1 | c.7578A>G p.A2526= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99676966; called by muse, mutect2, varscan2
- OR9G4 | c.930A>G p.P310= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100265244; called by muse, mutect2, varscan2
- PDCL3 | c.618A>G p.T206= | Silent (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2
- SDK2 | c.5295C>T p.S1765= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV101168397; called by muse, mutect2, varscan2
- SIGLEC14 | c.972G>A p.P324= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as rs755305403, COSV99707354; called by muse, mutect2, varscan2
- TENM3 | c.7761C>T p.N2587= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV101305286, COSV69306153; called by muse, mutect2, varscan2
- USP22 | c.786C>T p.D262= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs747593114, COSV99820454; called by muse, mutect2, varscan2
- ZAN | c.798T>C p.N266= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs1414511155, COSV100770225; called by muse, mutect2, varscan2
- SPTBN1 | c.148+32297G>A | Intron (SNP) | VAF 141/490 reads (29%) | catalogued as COSV100443302; called by muse, mutect2, varscan2
